Gene-level copy-number profile of tumor specimen TARGET-40-PAMYYJ-01A from TARGET case TARGET-40-PAMYYJ, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 17.7 years (6,477 days).
Specimen TARGET-40-PAMYYJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-OS.f3f6eee9-1168-5dfb-a768-113ee687f38c.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-40-PAMYYJ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 407 have no estimate.
https://portal.gdc.cancer.gov/files/6c22139d-9edb-46f1-9fa6-7c88b3dfcf14

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 21; copy number 1: 1,804; copy number 2: 11,238; copy number 3: 16,695; copy number 4: 19,143; copy number 5: 4,789; copy number 6: 5,269; copy number 7: 542; copy number 8: 296; copy number 9: 255; copy number 10: 156; copy number 12: 8.

Homozygous deletions (total copy number 0; autosomes only): 21 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:25,242,249–25,338,213, 1 gene (within-gene range 0–5): RSRP1.
- chr1:25,266,102–25,330,445, 3 genes: AL031432.2, RHD, SDHDP6.
- chr3:175,059,361–175,115,242, 2 genes: EEF1B2P8, NAALADL2-AS3.
- chr17:68,035,636–68,152,468, 9 genes: KPNA2, FBXO36P1, AC145343.1, LINC00674, LRRC37A16P, AC005332.6, AC005332.3, AC005332.5, SH3GL1P3.
- chr22:48,254,903–48,489,324, 6 genes: AL008720.1, MIR3201, AL008720.2, Z72006.1, Z82249.1, Z84468.2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 419 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:12,349,547–12,835,545, 1 gene, copy number 9 (within-gene range 6–9): CAMK1D.
- chr10:12,563,151–17,454,595, 89 genes, copy number 9 (broad region; genes not listed).
- chr12:66,767–1,647,212, 32 genes, copy number 10 (within-gene range 4–10): IQSEC3, AC026369.3, AC026369.1, AC026369.2, AC007406.3, SLC6A12, AC007406.1, SLC6A12-AS1, SLC6A13, AC007406.2, AC007406.4, KDM5A, CCDC77, B4GALNT3, NINJ2, AC006205.2, RNU7-103P, AC006205.1, NINJ2-AS1, LINC02455, WNK1, RNU4ATAC16P, AC004765.1, RAD52, AC004803.1, ERC1, HTR1DP1, AC004672.1, AC004672.2, LINC00942, WNT5B, FBXL14.
- chr17:15,229,773–17,512,266, 121 genes, copy number 10 (broad region; genes not listed).
- chr17:17,507,351–17,508,308, 1 gene, copy number 10: AC020558.2.
- chr17:19,296,596–22,205,154, 136 genes, copy number 9 (within-gene range 4–9) (broad region; genes not listed).
- chr17:65,100,812–65,227,703, 2 genes, copy number 10: RGS9, AC060771.1.
- chr17:67,784,753–67,996,469, 7 genes, copy number 9: RPL17P41, BPTF, AC134407.1, AC134407.2, AC134407.3, RN7SL622P, C17orf58.
- chr17:73,894,749–74,262,020, 8 genes, copy number 12: AC137735.1, AC137735.3, AC137735.2, LINC02074, RPL38, MGC16275, TTYH2, AC100786.1.
- chr22:16,405,330–16,748,645, 22 genes, copy number 9: AC137499.1, PABPC1P9, SLC9B1P4, ACTR3BP6, CHEK2P4, AP000547.2, AP000547.1, KCNMB3P1, CCT8L2, AP000547.4, FABP5P11, TPTEP1, AP000547.3, AP000365.1, SLC25A15P5, PARP4P3, ANKRD62P1-PARP4P3, ANKRD62P1, AC005301.1, VWFP1, AC005301.2, LINC01665.

Autosomal genes at a single copy (total copy number 1): 305. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
